MMRF case MMRF_2097 — Multiple Myeloma CoMMpass Study (MMRF-COMMPASS)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Plasma Cell Tumors; Primary site: Hematopoietic and reticuloendothelial systems. Index date (day 0 for every day count below): first treatment.
https://portal.gdc.cancer.gov/cases/82ae44ab-73c5-4774-af31-d25996841252

Demographics
Sex at birth: male; Age at index: 56 years; Vital status: Alive.

Diagnoses (1)
1. Multiple myeloma: ICD-O-3 morphology code: 9732/3; Tissue or organ of origin: Bone marrow; Site of resection or biopsy: Bone marrow; Age at diagnosis: 56.1 years (20,484 days); ISS stage: I; Days to last known disease status: 868 days (2.4 years); Days to last follow up: 868 days (2.4 years).
   Treatment given: Therapeutic agents: Cyclophosphamide; Regimen or line of therapy: First line of therapy; Days to treatment start: 1 day; Days to treatment end: 162 days.
   Treatment given: Therapeutic agents: Bortezomib; Regimen or line of therapy: First line of therapy; Days to treatment start: 7 days; Days to treatment end: 311 days.
   Treatment given: Therapeutic agents: Dexamethasone; Regimen or line of therapy: First line of therapy; Days to treatment start: 7 days.
   Treatment given: Therapeutic agents: Lenalidomide; Regimen or line of therapy: First line of therapy; Days to treatment start: 162 days.

Molecular and laboratory tests (laboratory values one line per visit day; values rounded to 3 significant figures where GDC's unit conversion carried more)
- Day -14: M Protein 0.1 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 734 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 5.8 mg/dL; Immunoglobulin A 0.35 g/L; Beta 2 Microglobulin 2.43 µg/mL; Lactate Dehydrogenase 3.72 µkat/L; Hemoglobin 9.24 mmol/L; Leukocytes 6 ×10⁹/L; Absolute Neutrophil 4.03 ×10⁹/L; Platelets 228 ×10⁹/L; Creatinine 74.3 µmol/L; Blood Urea Nitrogen 3.21 mmol/L; Calcium 2.23 mmol/L; Albumin 41 g/L; Total Protein 6 g/dL; Glucose 6 mmol/L.
- Day 63: M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 15.8 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.35 mg/dL; Immunoglobulin G 1.43 g/L; Immunoglobulin A 0.14 g/L; Immunoglobulin M 0.14 g/L; Lactate Dehydrogenase 4.7 µkat/L; Hemoglobin 8.8 mmol/L; Leukocytes 8.2 ×10⁹/L; Absolute Neutrophil 7.66 ×10⁹/L; Platelets 172 ×10⁹/L; Creatinine 78.7 µmol/L; Blood Urea Nitrogen 3.57 mmol/L; Calcium 2.33 mmol/L; Albumin 37 g/L; Total Protein 5.3 g/dL; Glucose 7.92 mmol/L.
- Day 190: M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 3.08 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.765 mg/dL; Immunoglobulin G 1.66 g/L; Immunoglobulin A 0.29 g/L; Immunoglobulin M 0.29 g/L; Lactate Dehydrogenase 5.3 µkat/L; Hemoglobin 8.12 mmol/L; Leukocytes 4.7 ×10⁹/L; Absolute Neutrophil 4.5 ×10⁹/L; Platelets 146 ×10⁹/L; Creatinine 75.1 µmol/L; Calcium 2.03 mmol/L; Albumin 31 g/L.
- Day 339 (ECOG 0): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.43 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.31 mg/dL; Immunoglobulin G 2.78 g/L; Immunoglobulin A 0.47 g/L; Immunoglobulin M 0.5 g/L; Lactate Dehydrogenase 4.02 µkat/L; Hemoglobin 8.99 mmol/L; Leukocytes 2.9 ×10⁹/L; Absolute Neutrophil 1.6 ×10⁹/L; Platelets 108 ×10⁹/L; Creatinine 85.7 µmol/L; Blood Urea Nitrogen 4.64 mmol/L; Calcium 2.28 mmol/L; Albumin 36 g/L; Total Protein 5.6 g/dL; Glucose 4.79 mmol/L.
- Day 430 (ECOG 0): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.39 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.882 mg/dL; Immunoglobulin G 3.77 g/L; Immunoglobulin A 0.71 g/L; Immunoglobulin M 0.51 g/L; Lactate Dehydrogenase 3.42 µkat/L; Hemoglobin 8.49 mmol/L; Leukocytes 3.2 ×10⁹/L; Absolute Neutrophil 1.8 ×10⁹/L; Platelets 145 ×10⁹/L; Creatinine 81.3 µmol/L; Blood Urea Nitrogen 4.64 mmol/L; Calcium 2.23 mmol/L; Albumin 33 g/L; Total Protein 5.5 g/dL; Glucose 4.57 mmol/L.
- Day 528 (ECOG 0): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 2.01 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.11 mg/dL; Immunoglobulin G 5.18 g/L; Immunoglobulin A 0.63 g/L; Immunoglobulin M 0.41 g/L; Lactate Dehydrogenase 3.43 µkat/L; Hemoglobin 8.93 mmol/L; Leukocytes 2.7 ×10⁹/L; Absolute Neutrophil 1.5 ×10⁹/L; Platelets 163 ×10⁹/L; Creatinine 81.3 µmol/L; Blood Urea Nitrogen 6.07 mmol/L; Calcium 2.3 mmol/L; Albumin 39 g/L; Total Protein 6.2 g/dL; Glucose 5.06 mmol/L.
- Day 622: M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.5 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.04 mg/dL; Lactate Dehydrogenase 3.92 µkat/L; Hemoglobin 9.18 mmol/L; Leukocytes 2.4 ×10⁹/L; Absolute Neutrophil 1.3 ×10⁹/L; Platelets 143 ×10⁹/L; Creatinine 90.2 µmol/L; Blood Urea Nitrogen 5 mmol/L; Calcium 2.3 mmol/L; Albumin 36 g/L; Total Protein 6 g/dL; Glucose 4.73 mmol/L.
- Day 686 (ECOG 0): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.19 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.949 mg/dL; Immunoglobulin G 4.58 g/L; Immunoglobulin A 0.6 g/L; Immunoglobulin M 0.44 g/L; Lactate Dehydrogenase 3.52 µkat/L; Hemoglobin 9.3 mmol/L; Leukocytes 2.4 ×10⁹/L; Absolute Neutrophil 0.91 ×10⁹/L; Platelets 142 ×10⁹/L; Creatinine 96.4 µmol/L; Blood Urea Nitrogen 5.71 mmol/L; Calcium 2.35 mmol/L; Albumin 36 g/L; Total Protein 5.8 g/dL; Glucose 4.57 mmol/L.
- Day 783: M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.29 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.724 mg/dL; Immunoglobulin G 5.08 g/L; Immunoglobulin A 0.57 g/L; Immunoglobulin M 0.39 g/L; Lactate Dehydrogenase 3.02 µkat/L; Creatinine 73.4 µmol/L; Blood Urea Nitrogen 5 mmol/L; Calcium 2.3 mmol/L; Albumin 43 g/L; Total Protein 5.7 g/dL; Glucose 4.79 mmol/L.
- Day 868: M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.37 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.867 mg/dL; Immunoglobulin G 5.33 g/L; Immunoglobulin A 0.51 g/L; Immunoglobulin M 0.42 g/L; Lactate Dehydrogenase 3.18 µkat/L; Hemoglobin 8.99 mmol/L; Leukocytes 2.6 ×10⁹/L; Absolute Neutrophil 1.3 ×10⁹/L; Platelets 164 ×10⁹/L; Creatinine 76.9 µmol/L; Blood Urea Nitrogen 5.71 mmol/L; Calcium 2.23 mmol/L; Albumin 36 g/L; Total Protein 5.7 g/dL; Glucose 4.46 mmol/L.

Other clinical attributes
- Day -14: Weight: 78 kg; Height: 180 cm.

Family history
- Relative with cancer history: yes; Relationship type: Father; Relationship sex at birth: male.

Biospecimens (2 samples)
- Sample MMRF_2097_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS; Days to sample procurement: -14 days.
- Sample MMRF_2097_2_PB_Whole: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS; Days to sample procurement: -14 days.
